Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3986, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3986-01A (Primary Tumor).

Diagnosis (diagnoses):

Resected colon sample with a moderately differentiated adenocarcinoma of the colorectal type, measuring a max of 5.5 cm in diameter, with infiltration of the tunica muscularis propria up to the border of the pericolic fatty tissue.

The tumor stage is: pT2, pN0 (0/27) pMX; G2, L0, V0, R0

Source: NCI Genomic Data Commons file dfc1627a-b442-4ab7-befd-f3066d5df929 (TCGA-AA-3986.5CA738D3-2A5E-4DB2-A064-FE61A9CEC8B3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).